Surgical pathology report (de-identified scan), TCGA case TCGA-BR-6453, project TCGA-STAD (Stomach Adenocarcinoma), tissue source site Asterand, specimen TCGA-BR-6453-01A (Primary Tumor).

[page 1 of 2]
[REDACTED]

[REDACTED]		Case ID	Subject ID	Formatted Path Report
[REDACTED]		[REDACTED]	[REDACTED]	STOMACH TISSUE CHECKLIST Specimen type: Gastrectomy Tumor site: Stomach Tumor size: Not specified Tumor features: Ulcerated Histologic type: Adenocarcinoma Histologic grade: Poorly differentiated Tumor extent: Muscularis propria Lymph nodes: 1/1 positive for metastasis (Intraabdominal 1/1) Lymphatic invasion: Not specified Venous invasion: Not specified Perineural invasion: Not specified Margins: Not specified Evidence of neo-adjuvant treatment: Not specified Additional pathologic findings: Not specified Comments: None

[page 2 of 2]
Date of Procurement

Source: NCI Genomic Data Commons file 0f9102c5-b9ea-4454-b817-1e2f077e72a8 (TCGA-BR-6453.87B733AD-3E9C-41CE-9E1D-B874F242950E.PDF), Data Release 46.0 - August 10, 2026; text from the OCR (chandra-v1.5.0).